Somatic mutation profile of tumor specimen TCGA-D8-A1JK-01A (aliquot TCGA-D8-A1JK-01A-11D-A13L-09) from TCGA case TCGA-D8-A1JK, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-D8-A1JK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0424262-9251-45b7-b813-6c442a3ac916.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1JK-10A (Blood Derived Normal), aliquot TCGA-D8-A1JK-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41958495-ab36-45e5-8741-358e7329e2e2

The open-access MAF lists 222 somatic variants for this specimen: 169 protein-altering or splice-affecting, 49 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 49, Frame Shift Del 17, Nonsense Mutation 11, Splice Site 3, In Frame Del 2, RNA 2, Splice Region 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 25/95 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STAT3 | c.1151T>A p.F384Y | Missense Mutation (SNP) | VAF 61/132 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as CM076549, CM146780, COSV52889773; called by muse, mutect2, varscan2
- TP53 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 67/128 reads (52%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- A2M | c.4273C>T p.Q1425* | Nonsense Mutation (SNP) | VAF 12/110 reads (11%) | catalogued as COSV59389231; called by muse, varscan2
- ADAM2 | c.1525T>G p.S509A | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99697500; called by muse, mutect2, varscan2
- ADAMTS5 | c.1648C>A p.Q550K | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.024); catalogued as COSV53178617, COSV53180986; called by muse, mutect2, varscan2
- ADGRF4 | c.2072T>C p.M691T | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as COSV51954376; called by muse, mutect2, varscan2
- ADGRG5 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV61083860; called by muse, mutect2, varscan2
- AGPS | c.603G>A p.M201I | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV51563103; called by muse, mutect2
- AGTPBP1 | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV61274146; called by muse, varscan2
- AMBN | c.96G>T p.Q32H | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.876); catalogued as COSV59826984; called by muse, mutect2, varscan2
- ANO7 | c.800C>G p.P267R (on ENST00000274979; = p.P213R on NM_001370694.2) | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs764530986, COSV51474458, COSV99238828; called by muse, mutect2, varscan2
- APC | c.3811T>A p.F1271I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV57358818; called by muse, mutect2, varscan2
- ASCC3 | c.4585T>A p.F1529I | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV64977555; called by muse, varscan2
- ASCC3 | c.4538T>G p.F1513C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100976619; called by muse, varscan2
- ASH1L | c.6442del p.E2148Nfs*18 (on ENST00000368346 / NM_001366177.2; = p.E2143Nfs*18 on NM_018489.3) | Frame Shift Del (DEL) | VAF 54/224 reads (24%) | catalogued as COSV100853630, COSV64210334; called by mutect2, pindel, varscan2
- ASXL1 | c.2024C>T p.P675L | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as COSV100039749; called by muse, mutect2
- ATP10B | c.3863T>A p.V1288E | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV100515187; called by muse, mutect2
- ATP9B | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200396916, COSV56955270; called by muse, mutect2, varscan2
- BAZ2A | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.9); catalogued as COSV51639590, COSV99465754; called by muse, mutect2, varscan2
- BCAS1 | c.1348A>T p.M450L | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.131); catalogued as COSV101006273; called by muse, mutect2
- BRWD1 | c.773G>T p.R258I | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV58122521; called by muse, mutect2, varscan2
- C2CD3 | c.940A>T p.K314* | Nonsense Mutation (SNP) | VAF 52/80 reads (65%) | catalogued as COSV100487223, COSV58095333; called by muse, mutect2, varscan2
- C3AR1 | c.1159C>G p.L387V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.176); catalogued as COSV50820486; called by muse, mutect2, varscan2
- C3orf70 | c.324T>A p.F108L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV58589064; called by muse, mutect2, varscan2
- C7 | c.2037G>C p.W679C | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57476638; called by muse, mutect2, varscan2
- CA14 | c.469C>A p.L157M | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52529874; called by muse, mutect2, varscan2
- CCDC174 | c.644G>C p.R215P | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57981483; called by muse, mutect2, varscan2
- CCDC71 | c.1082G>A p.R361K | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as COSV58910341; called by muse, mutect2, varscan2
- CD93 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV55666689; called by muse, mutect2, varscan2
- CDC42BPA | c.4475T>C p.L1492S (on ENST00000334218 / NM_001366019.2; = p.L1479S on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs768503352, COSV100505679; called by muse, mutect2
- CDC42EP2 | c.158G>C p.G53A | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54203610; called by muse, mutect2, varscan2
- CEP85 | c.1541C>G p.T514S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV53330791; called by muse, mutect2, varscan2
- CFAP44 | c.443A>C p.N148T | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV55613320, COSV55613596; called by muse, mutect2, varscan2
- CHD5 | c.5458C>T p.H1820Y | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV52419312; called by muse, mutect2, varscan2
- CHD5 | c.2927del p.G976Afs*11 | Frame Shift Del (DEL) | VAF 105/260 reads (40%) | catalogued as COSV52420551; called by mutect2, pindel, varscan2
- CHIC2 | c.38A>C p.D13A | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); catalogued as COSV55755674; called by muse, mutect2, varscan2
- CPT2 | c.312A>T p.K104N | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.154); catalogued as COSV101017455; called by muse, mutect2, varscan2
- CSAD | c.16G>T p.A6S (on ENST00000444623 / NM_001244705.2; = p.A33S on NM_015989.5) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV57243833; called by muse, mutect2, varscan2
- CSMD1 | c.1793C>A p.S598* (on ENST00000520002; = p.S597* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV59346751; called by muse, mutect2, varscan2
- CSRNP3 | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58777487, COSV58781498; called by muse, mutect2, varscan2
- CTNNA2 | c.1451T>C p.V484A | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.017); catalogued as COSV58163019; called by muse, mutect2, varscan2
- CUBN | c.5759C>T p.A1920V | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV64720663; called by muse, mutect2, varscan2
- CYP8B1 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60226930; called by muse, mutect2
- DAAM1 | c.645G>C p.E215D | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as COSV62837768; called by muse, mutect2, varscan2
- DENND4A | c.4160A>G p.Q1387R | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.115); catalogued as COSV101475368; called by muse, mutect2
- DLGAP1 | c.1701G>T p.Q567H | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV59817413; called by muse, mutect2, varscan2
- DMXL1 | c.3253T>C p.S1085P | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100224252; called by muse, mutect2
- DNAJC13 | c.6379C>A p.Q2127K | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV53453885; called by muse, mutect2, varscan2
- DOCK10 | c.2906A>C p.K969T | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.21); catalogued as COSV51420384; called by muse, mutect2, varscan2
- DST | c.7189A>C p.S2397R | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV55025150; called by muse, mutect2, varscan2
- DYNC1H1 | c.4199T>C p.V1400A | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.814); catalogued as rs1224711745, COSV64139049; called by muse, mutect2, varscan2
- DYNC1LI2 | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 46/308 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV50755280; called by muse, mutect2, varscan2
- EFCAB6 | c.1540C>G p.R514G | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs552883535, COSV99413601; called by muse, mutect2
- EIF2AK4 | c.577A>T p.K193* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as COSV55470505; called by muse, mutect2, varscan2
- EPB41L4B | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.672); catalogued as COSV65797739; called by muse, mutect2, varscan2
- EVA1C | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV55825275; called by muse, mutect2, varscan2
- FAM166C | c.590T>G p.F197C | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99994904; called by muse, mutect2
- FASN | c.5363A>G p.N1788S | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100147939; called by muse, mutect2
- FAT4 | c.11840A>C p.N3947T | Missense Mutation (SNP) | VAF 96/280 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV58695542; called by muse, mutect2, varscan2
- FLG | c.425A>T p.K142M | Missense Mutation (SNP) | VAF 44/383 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV64244457; called by muse, mutect2, varscan2
- FNDC1 | c.4406C>T p.T1469I | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.286); catalogued as COSV51942373; called by muse, mutect2, varscan2
- FZD8 | c.261C>G p.F87L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV65968108; called by muse, mutect2, varscan2
- G6PD | c.1527G>A p.W509* | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as COSV63703677; called by muse, mutect2, varscan2
- GIGYF2 | c.668del p.A223Vfs*56 | Frame Shift Del (DEL) | VAF 43/148 reads (29%) | catalogued as COSV65251239; called by mutect2, pindel, varscan2
- GMEB1 | c.347T>A p.I116K | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99603293; called by muse, mutect2
- GPR89B | c.1039C>A p.L347I | Missense Mutation (SNP) | VAF 50/442 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.672); catalogued as rs1345822110; called by muse, varscan2
- GRIA4 | c.2079G>T p.W693C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56906578; called by muse, mutect2, varscan2
- GSS | c.1139T>C p.V380A | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV53625970; called by muse, mutect2, varscan2
- HCAR3 | c.242C>G p.P81R | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757339733, COSV100811634, COSV63675712; called by muse, varscan2
- HS3ST2 | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 23/102 reads (23%) | catalogued as COSV54464761; called by muse, mutect2, varscan2
- IL1RAP | c.1068C>A p.Y356* | Nonsense Mutation (SNP) | VAF 70/232 reads (30%) | catalogued as COSV50764974; called by muse, mutect2, varscan2
- INPP5D | c.1934G>A p.R645H (on ENST00000445964 / NM_001017915.3; = p.R644H on NM_005541.5) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781285468, COSV64038411; called by muse, mutect2, varscan2
- ITPR3 | c.5959G>C p.D1987H | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV65411776; called by muse, mutect2, varscan2
- KAT6A | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as rs1564044797, COSV99705322; called by muse, mutect2
- KCNK9 | c.73G>T p.V25L | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV57284676; called by muse, mutect2, varscan2
- KDM4C | c.1439T>A p.I480K | Missense Mutation (SNP) | VAF 82/134 reads (61%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV67188629; called by muse, mutect2, varscan2
- KIAA1109 | c.8210G>A p.S2737N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.15); catalogued as COSV52681703; called by muse, mutect2, varscan2
- KIF4B | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV70530280; called by muse, mutect2, varscan2
- KMT5B | c.309C>T p.S103= | Splice Region (SNP) | VAF 31/75 reads (41%) | catalogued as rs1246502640, COSV58566012; called by muse, mutect2, varscan2
- LPIN2 | c.1231C>A p.L411I | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55241507; called by muse, mutect2, varscan2
- LRP2 | c.2233G>A p.G745R | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1201105990, COSV55561518; called by muse, mutect2, varscan2
- LRRC8C | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64999451; called by muse, mutect2, varscan2
- LRRIQ1 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 10/132 reads (8%) | catalogued as COSV101277722; called by muse, mutect2
- MDM4 | c.143_144del p.T48Sfs*2 | Frame Shift Del (DEL) | VAF 13/93 reads (14%) | catalogued as COSV65797960; called by mutect2, pindel, varscan2
- MPP5 | c.1363A>C p.N455H | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV55530825; called by muse, mutect2, varscan2
- NCAPH | c.959C>G p.A320G | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs372098005, COSV53637283; called by muse, mutect2, varscan2
- NCOR1 | c.2079G>T p.E693D | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.132); catalogued as COSV51983553, COSV51987436; called by muse, mutect2, varscan2
- NHS | c.4541C>T p.S1514F | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66278248; called by muse, mutect2, varscan2
- NOS1AP | c.314A>T p.K105M | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62637047; called by muse, mutect2, varscan2
- NPAS3 | c.1499G>A p.R500Q (on ENST00000356141 / NM_001164749.2; = p.R468Q on NM_022123.3) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.078); catalogued as rs144067606; called by muse, mutect2, varscan2
- NVL | c.2401T>G p.S801A | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.076); catalogued as COSV55873791; called by muse, mutect2, varscan2
- OR2T8 | c.251T>C p.L84S | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV60663475; called by muse, mutect2, varscan2
- OR4N2 | c.795C>A p.F265L | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as COSV100269698, COSV60051246; called by muse, mutect2
- PASD1 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as COSV64856206; called by muse, mutect2, varscan2
- PCK2 | c.1270T>C p.F424L | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53748878; called by muse, mutect2, varscan2
- PDE3A | c.3003G>T p.Q1001H | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62976895; called by muse, mutect2, varscan2
- PDP1 | c.803C>A p.A268E | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99892551; called by muse, mutect2
- PDP1 | c.805T>A p.F269I | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV99892555; called by muse, mutect2
- PIGZ | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53014100; called by muse, mutect2, varscan2
- PIKFYVE | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs369920151, COSV52244499; called by muse, mutect2, varscan2
- PLXNA4 | c.532A>G p.N178D | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs766762723, COSV58141133; called by mutect2, varscan2
- POLG2 | c.1301A>G p.E434G | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101604427; called by muse, mutect2, varscan2
- POU2F1 | c.1870G>A p.G624S (on ENST00000541643 / NM_001365848.1; = p.G647S on NM_002697.4) | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs371507009, COSV54820289; called by muse, mutect2, varscan2
- PRKDC | c.922T>G p.L308V | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100041102; called by muse, mutect2
- PRRC2B | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs1308552617, COSV61939562; called by muse, mutect2, varscan2
- RACGAP1 | c.1658T>G p.L553R | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV100407830, COSV56700377; called by muse, mutect2
- RAD54B | c.1423G>C p.D475H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100279873; called by muse, mutect2
- RBM25 | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV99998787; called by muse, mutect2, varscan2
- REC8 | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs371804350; called by muse, mutect2, varscan2
- RNF17 | c.2234C>G p.A745G | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55044770; called by muse, mutect2, varscan2
- RUFY3 | c.1065A>T p.L355F | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV56915236; called by muse, mutect2, varscan2
- SCG2 | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100544773, COSV59539954; called by muse, mutect2
- SEPTIN14 | c.347G>A p.G116D | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66428927; called by muse, mutect2, varscan2
- SHOX2 | c.971A>G p.K324R (on ENST00000441443 / NM_006884.3; = p.K348R on NM_003030.4) | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.925); catalogued as rs753586895, COSV101273806; called by muse, mutect2, varscan2
- SLC10A7 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV53886839; called by muse, mutect2, varscan2
- SLC12A8 | c.1283A>G p.H428R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV58866421, COSV58868033; called by muse, mutect2, varscan2
- SLC22A6 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV100842851, COSV100842920; called by muse, mutect2
- SLC45A3 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100901224; called by muse, mutect2
- SLC5A10 | c.1766T>C p.I589T (on ENST00000395645 / NM_001042450.4; = p.I605T on NM_152351.5) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV99408220; called by muse, mutect2
- SLC7A5 | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV55365387; called by muse, mutect2, varscan2
- SLC9A2 | c.538A>G p.N180D | Missense Mutation (SNP) | VAF 43/342 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99296375; called by muse, mutect2, varscan2
- SPOPL | c.613T>C p.F205L | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV54514601; called by muse, mutect2, varscan2
- SRP54 | c.1139A>C p.D380A | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV53740621; called by muse, mutect2, varscan2
- SYTL3 | c.338A>G p.K113R | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.263); catalogued as rs969789741, COSV51912116; called by muse, mutect2, varscan2
- TAS2R14 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.74); catalogued as COSV67858441; called by muse, mutect2, varscan2
- TCTN1 | c.1623C>A p.A541= (on ENST00000551590 / NM_001173975.3; = p.A527= on NM_024549.6) | Splice Region (SNP) | VAF 12/60 reads (20%) | catalogued as COSV54373196; called by muse, varscan2
- TDRKH | c.1408T>A p.Y470N | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs1242073267, COSV100162561; called by muse, mutect2
- TEX33 | c.694A>G p.K232E (on ENST00000381821 / NM_001163857.2; = p.K147E on NM_178552.4) | Missense Mutation (SNP) | VAF 85/165 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV67822160; called by muse, mutect2, varscan2
- THNSL1 | c.1259T>G p.I420R | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV64479557; called by muse, mutect2, varscan2
- TMEM37 | c.183G>A p.W61* | Nonsense Mutation (SNP) | VAF 7/88 reads (8%) | catalogued as COSV99191615; called by muse, mutect2
- TMEM81 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV52705575; called by muse, mutect2, varscan2
- TNC | c.3047G>A p.R1016H | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777700259, COSV60780296; called by muse, mutect2, varscan2
- TRAFD1 | c.1371T>A p.N457K | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV57505099; called by muse, mutect2, varscan2
- TRIM42 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.059); catalogued as COSV53884666; called by muse, mutect2, varscan2
- TTN | c.55496A>G p.N18499S (on ENST00000591111; = p.N11075S on NM_003319.4) | Missense Mutation (SNP) | VAF 38/182 reads (21%) | PolyPhen benign (0.007); catalogued as rs1187229401, COSV60176597; called by muse, mutect2, varscan2
- UFL1 | c.1884C>G p.N628K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV65150189; called by muse, mutect2, varscan2
- ULBP2 | c.545T>C p.F182S | Missense Mutation (SNP) | VAF 61/421 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100951239; called by muse, mutect2, varscan2
- UQCRC1 | c.1235A>G p.D412G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV99178988; called by muse, mutect2, varscan2
- VRK1 | c.883_886del p.K295Qfs*11 | Frame Shift Del (DEL) | VAF 13/110 reads (12%) | catalogued as rs779282547; called by pindel, varscan2
- WRNIP1 | c.1004A>C p.K335T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66355771; called by muse, mutect2
- YY1AP1 | c.250G>A p.E84K (on ENST00000295566 / NM_139118.2; = p.E7K on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV55122936; called by muse, mutect2, varscan2
- ZBBX | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.022); catalogued as rs760372262, COSV56794402; called by muse, mutect2, varscan2
- ZFHX4 | c.3797C>T p.T1266M | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs763149017, COSV51467227; called by muse, mutect2, varscan2
- ZMYM4 | c.1570-1G>A p.X524_splice | Splice Site (SNP) | VAF 12/107 reads (11%) | catalogued as COSV58913503; called by muse, mutect2, varscan2
- ZNF217 | c.2028C>A p.Y676* | Nonsense Mutation (SNP) | VAF 97/346 reads (28%) | catalogued as COSV56599449; called by muse, mutect2, varscan2
- ZNF433 | c.1847A>T p.K616I | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV61399771; called by muse, mutect2, varscan2
- ZNF587 | c.1511G>T p.S504I | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as COSV57149466; called by muse, mutect2, varscan2
- ZNF618 | c.2761G>C p.G921R (on ENST00000374126 / NM_001318042.2; = p.G828R on NM_133374.2) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs757782164, COSV55924946; called by muse, mutect2, varscan2
- ZRANB3 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV51507438; called by muse, mutect2, varscan2
- ALCAM | c.1212_1215del p.R405Sfs*3 | Frame Shift Del (DEL) | VAF 21/69 reads (30%) | called by mutect2, pindel, varscan2
- AREG | c.474A>T p.E158D | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2
- ARMC1 | c.324_325del p.I109Sfs*10 | Frame Shift Del (DEL) | VAF 82/211 reads (39%) | called by mutect2, pindel, varscan2
- CEP55 | c.62_75del p.S21Yfs*18 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- CLIP1 | c.3501_3502del p.K1168Vfs*13 (on ENST00000620786 / NM_001247997.1; = p.K1157Vfs*13 on NM_002956.2) | Frame Shift Del (DEL) | VAF 21/99 reads (21%) | called by mutect2, pindel, varscan2
- CLNS1A | c.637_638del p.D213Lfs*2 | Frame Shift Del (DEL) | VAF 17/117 reads (15%) | called by pindel, varscan2
- EYS | c.895_896del p.V299Ffs*13 | Frame Shift Del (DEL) | VAF 16/136 reads (12%) | called by pindel, varscan2
- FBXO5 | c.1204_1218del p.G402_C406del | In Frame Del (DEL) | VAF 20/179 reads (11%) | called by mutect2, pindel
- KLRB1 | c.451_452del p.L151Vfs*25 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- MYC | c.472G>C p.D158H (on ENST00000377970; = p.D173H on NM_002467.6) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2
- OPCML | c.645del p.V216* | Frame Shift Del (DEL) | VAF 31/108 reads (29%) | called by mutect2, pindel, varscan2
- RARB | c.1172-10_1190del p.X391_splice (on ENST00000383772 / NM_001290216.2; = p.X384_splice on NM_000965.5 and 3 other RefSeq transcripts) | Splice Site (DEL) | VAF 7/58 reads (12%) | called by mutect2, pindel
- RLF | c.3793_3794del p.E1265Kfs*2 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- SYNRG | c.2655T>A p.N885K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- SYNRG | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TBX3 | c.140_162del p.P47Lfs*56 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- ZC3H11A | c.1563_1565del p.K521del | In Frame Del (DEL) | VAF 16/170 reads (9%) | called by pindel, varscan2
- ZNF33A | c.1864_1865del p.Q622Tfs*15 (on ENST00000458705 / NM_006974.3; = p.Q623Tfs*15 on NM_006954.2) | Frame Shift Del (DEL) | VAF 16/164 reads (10%) | called by pindel, varscan2
- ZNF486 | c.814_829del p.G272Tfs*10 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- ABCC1 | c.3261C>A p.I1087= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV60689214; called by muse, mutect2, varscan2
- ADAM9 | c.2412T>A p.I804= | Silent (SNP) | VAF 247/407 reads (61%) | catalogued as COSV65951202; called by muse, mutect2, varscan2
- ADCK2 | c.210C>T p.V70= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs764063490, COSV50782264; called by muse, mutect2, varscan2
- APOB | c.7884A>G p.S2628= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs1417847805, COSV51942622; called by muse, mutect2, varscan2
- ARHGAP5 | c.2295C>T p.S765= | Silent (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- ASXL3 | c.6657C>T p.A2219= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as rs765224501, COSV52471713; called by muse, mutect2, varscan2
- BRD7 | c.1869C>A p.V623= | Silent (SNP) | VAF 41/124 reads (33%) | catalogued as COSV54268526; called by muse, mutect2, varscan2
- C5 | c.4197C>T p.Y1399= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV56329566; called by muse, mutect2, varscan2
- CCDC125 | c.213A>G p.E71= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV67288404; called by muse, mutect2, varscan2
- CD63 | c.717G>A p.*239= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs757575130, COSV57676712; called by muse, mutect2, varscan2
- CHODL | c.720C>T p.F240= | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as COSV54733674; called by muse, mutect2, varscan2
- DISP1 | c.2808T>G p.A936= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as COSV99451259; called by muse, mutect2, varscan2
- EFCAB14 | c.1284C>T p.I428= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as rs769658328, COSV64239728; called by muse, mutect2, varscan2
- ELK1 | c.15G>A p.V5= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV55953781; called by muse, mutect2, varscan2
- ELN | c.1299G>A p.P433= | Silent (SNP) | VAF 27/279 reads (10%) | catalogued as rs367742656; called by muse, mutect2, varscan2
- GABRQ | c.1212G>A p.A404= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs75916692, COSV64782953; called by muse, mutect2, varscan2
- IFT80 | c.2040T>G p.L680= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV100424849; called by muse, mutect2, varscan2
- INTS14 | c.1497T>C p.Y499= (on ENST00000313182 / NM_001366360.2; = p.Y420= on NM_001136043.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV56011958; called by muse, mutect2, varscan2
- ITGB1 | c.285A>G p.V95= | Silent (SNP) | VAF 114/326 reads (35%) | catalogued as COSV56483763; called by muse, mutect2, varscan2
- KIF1B | c.816T>C p.N272= | Silent (SNP) | VAF 28/172 reads (16%) | catalogued as COSV55811504; called by muse, mutect2, varscan2
- KIR2DL4 | c.639C>T p.I213= (on ENST00000396284; = p.I174= on NM_001080770.2) | Silent (SNP) | VAF 49/467 reads (10%) | called by muse, mutect2, varscan2
- KLF15 | c.442C>T p.L148= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV56180492; called by muse, mutect2, varscan2
- MEX3C | c.1734T>A p.P578= | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- MPDZ | c.573C>T p.I191= | Silent (SNP) | VAF 26/207 reads (13%) | catalogued as COSV59947127; called by muse, mutect2, varscan2
- MROH7 | c.3936G>A p.Q1312= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs1557736308, COSV64887739; called by muse, mutect2, varscan2
- MTCL1 | c.3090C>A p.L1030= (on ENST00000306329 / NM_001378206.1; = p.L711= on NM_015210.4) | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV60403651, COSV60408422; called by muse, mutect2, varscan2
- MYH15 | c.2829G>A p.E943= | Silent (SNP) | VAF 34/221 reads (15%) | catalogued as COSV56314170; called by muse, mutect2, varscan2
- MYH4 | c.2448C>T p.F816= | Silent (SNP) | VAF 60/175 reads (34%) | catalogued as COSV55121884; called by muse, mutect2, varscan2
- NAGK | c.12C>A p.I4= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV99730666; called by muse, mutect2
- NMUR2 | c.535C>T p.L179= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV54920741; called by muse, mutect2, varscan2
- OTUD5 | c.1509C>T p.A503= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs781965927, COSV50237260; called by muse, mutect2
- PC | c.2289C>T p.F763= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV100547117; called by muse, mutect2, varscan2
- RB1CC1 | c.4344T>C p.N1448= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as COSV50256380; called by muse, mutect2, varscan2
- RFX3 | c.2226A>G p.T742= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as rs757761534, COSV65862376; called by muse, mutect2, varscan2
- RGL3 | c.159C>T p.P53= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100710526, COSV62698431; called by muse, mutect2, varscan2
- ROCK1 | c.1893T>C p.I631= | Silent (SNP) | VAF 57/190 reads (30%) | catalogued as rs1457902680, COSV67697100; called by muse, mutect2, varscan2
- RUFY3 | c.1066C>A p.R356= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV56915267, COSV56917079; called by muse, mutect2, varscan2
- SI | c.3663T>C p.Y1221= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs767992819, COSV52287747; called by muse, mutect2, varscan2
- SNX16 | c.126C>T p.G42= | Silent (SNP) | VAF 14/139 reads (10%) | catalogued as COSV100629626; called by muse, mutect2, varscan2
- SULF1 | c.549A>G p.G183= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV99483316; called by muse, mutect2, varscan2
- SYNM | c.4617G>A p.R1539= (on ENST00000336292 / NM_145728.3; = p.R1227= on NM_015286.6) | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs782347134, COSV50442718; called by muse, mutect2, varscan2
- SYT17 | c.363C>T p.L121= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs1291455600, COSV62547049; called by muse, mutect2, varscan2
- TAS2R8 | c.414T>C p.F138= | Silent (SNP) | VAF 17/124 reads (14%) | catalogued as COSV53689504; called by muse, mutect2, varscan2
- TLCD3A | c.312T>A p.R104= | Silent (SNP) | VAF 40/76 reads (53%) | catalogued as COSV56746575; called by muse, mutect2, varscan2
- TSEN54 | c.1398T>G p.P466= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV51368957; called by muse, mutect2, varscan2
- TTC7A | c.1110G>A p.E370= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as COSV55412997; called by muse, mutect2, varscan2
- WASHC2C | c.969C>A p.L323= | Silent (SNP) | VAF 16/243 reads (7%) | called by muse, mutect2
- ZBTB11 | c.2868C>T p.N956= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs762326730, COSV57245852; called by muse, mutect2, varscan2
- ZNF182 | c.471C>T p.P157= | Silent (SNP) | VAF 31/143 reads (22%) | catalogued as rs782514467, COSV59355643; called by muse, mutect2, varscan2
- AC016747.4 | n.551G>T | RNA (SNP) | VAF 33/156 reads (21%) | catalogued as COSV54376443; called by muse, mutect2, varscan2
- ACBD4 | chr17:45143509 T>C | 3'Flank (SNP) | VAF 21/51 reads (41%) | catalogued as COSV58852640; called by muse, mutect2, varscan2
- CABYR | c.*40G>T | 3'UTR (SNP) | VAF 25/141 reads (18%) | catalogued as COSV59111633; called by muse, mutect2, varscan2
- OR3A4P | n.1057T>C | RNA (SNP) | VAF 34/125 reads (27%) | called by muse, mutect2, varscan2
